FM case AD17257 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/a7bb5bf3-54cc-4338-bf2f-3a9a57f7cf2b

Female, 47.5 years: Adrenal cortical carcinoma (ICD-O-3 8370/3) of the adrenal gland; metastasis biopsied or resected from the adrenal gland. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
